Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6922, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6922-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 4

Date:

Examination: Histopathological examination (cito)

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Multiple organ resection – sigmoid colon**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the sigmoid colon**

Examination performed on:

Macroscopic description:

A 15.2 cm length of the large intestine with a piece of mesentery sized 15 x 6.5 x 2.5 cm. Ulcerous tumour sized 4.2 x 6.5 x 0.8 cm in the mucosa. The lesion surrounding 90% of the intestine circumference, removed 7.2 cm from the incision line and 5.3 cm from the opposite one.

Microscopic description:**Adenocarcinoma tubulopapillare (G2).****Infiltratio carcinomatosa profunda tunicae muscularis propriae et telae adiposae mesenterii pericolicae.****Incision lines free of neoplastic lesions.****Metastases carcinomatosae in lymphonodo (NO I/VIII).****Infiltratio carcinomatosa capsulae lymphonodi.****Emboliae carcinomatosae.**Histopathological Diagnosis:**Adenocarcinoma tubulopapillare coli. Tubulopapillar adenocarcinoma of the colon.****Metastases carcinomatosae in lymphonodo. Cancer metastases in the lymph nodes (NO I/VIII).****(G2, Dukes C, Astler - Coller, C2, pT3, pN1).**

Compliance validated by:

CONTACT YOU DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file bd9d68d5-a178-49be-a016-6581c90b0fb9 (TCGA-D5-6922.424D8FF7-23F7-4396-8747-F85A4C6E0A3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).